Somatic mutation profile of tumor specimen ALCH-AEL4-TTR1-A (aliquot ALCH-AEL4-TTR1-A-7-0-D-A777-36) from ALCHEMIST case ALCH-AEL4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.1 years (24,862 days).
Specimen ALCH-AEL4-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2af78182-fd1a-47ca-b20d-b6170e675567.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEL4-NB1-A (Blood Derived Normal), aliquot ALCH-AEL4-NB1-A-1-0-D-A596-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9586f9ba-dc56-4ae3-8908-3745638af056

The open-access MAF lists 187 somatic variants for this specimen: 131 protein-altering or splice-affecting, 37 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 37, Intron 9, Nonsense Mutation 5, Splice Site 5, 5'UTR 3, 3'UTR 3, Splice Region 2, Frame Shift Ins 2, RNA 2, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LDLR | c.327C>A p.C109* | Nonsense Mutation (SNP) | VAF 38/107 reads (36%) | catalogued as rs1057519654; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC093155.3 | c.868C>G p.H290D | Missense Mutation (SNP) | VAF 25/105 reads (24%) | PolyPhen benign (0.003); catalogued as COSV100777842; called by muse, mutect2, varscan2
- ATAD2 | c.1804G>C p.E602Q | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV54884237; called by muse, mutect2
- BSN | c.11353C>G p.L3785V | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.063); catalogued as COSV56523031; called by muse, mutect2, varscan2
- C2CD4B | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs753967216, COSV66791243; called by muse, mutect2, varscan2
- CNTN3 | c.2369G>T p.S790I | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99726198; called by muse, mutect2
- COL6A3 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1278327904, COSV55084799; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLGAP4 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1317471180; called by muse, mutect2, varscan2
- DPYSL4 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1419103594; called by muse, mutect2, varscan2
- EXOC3L1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs148946258; called by muse, mutect2, varscan2
- FAT1 | c.13546C>T p.H4516Y | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101499352, COSV101499415; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as rs747123659; called by muse, mutect2, varscan2
- GAS2 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53404080; called by muse, mutect2
- HOXB2 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1295771921; called by muse, mutect2, varscan2
- HYKK | c.338-1G>C p.X113_splice | Splice Site (SNP) | VAF 6/82 reads (7%) | catalogued as COSV64762478; called by muse, mutect2
- KCNA7 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750280618, COSV55502938; called by muse, mutect2, varscan2
- KLHL1 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs1278478249; called by muse, mutect2, varscan2
- LAMA3 | c.8592C>G p.I2864M (on ENST00000313654 / NM_198129.4; = p.I1255M on NM_000227.6) | Missense Mutation (SNP) | VAF 253/1070 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52535196; called by muse, mutect2, varscan2
- LRRC4B | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65350214; called by muse, mutect2, varscan2
- MED20 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 76/3002 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV54826582; called by muse, mutect2
- MGAT5B | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1276030428, COSV56929704; called by muse, mutect2
- MIA2 | c.1018G>C p.D340H | Missense Mutation (SNP) | VAF 45/448 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV54482561; called by muse, mutect2, varscan2
- MIOX | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs1345608531, COSV53313420, COSV99327115; called by muse, mutect2, varscan2
- MRPS31 | c.441-1G>A p.X147_splice | Splice Site (SNP) | VAF 12/27 reads (44%) | catalogued as COSV60266648; called by muse, varscan2
- NALCN | c.3358G>A p.V1120M | Missense Mutation (SNP) | VAF 100/196 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.869); catalogued as COSV51966520; called by muse, mutect2, varscan2
- PRR12 | c.2198C>T p.T733M (on ENST00000615927; = p.T1554M on NM_020719.3) | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as rs757185520; called by muse, mutect2, varscan2
- PSMD7 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 78/310 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1433247617, COSV54697800; called by muse, mutect2, varscan2
- PXDNL | c.3964C>G p.Q1322E | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62499114; called by muse, mutect2, varscan2
- RBM44 | c.1078C>T p.R360C (on ENST00000611254; = p.R994C on NM_001080504.2) | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs778768338; called by muse, mutect2, varscan2
- REL | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 83/278 reads (30%) | catalogued as COSV99691909; called by muse, mutect2, varscan2
- REM1 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 53/250 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as rs1207791401; called by muse, mutect2, varscan2
- RGS11 | c.1074C>G p.F358L (on ENST00000397770 / NM_183337.3; = p.F337L on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV51453725; called by muse, mutect2, varscan2
- RSRC2 | c.892C>G p.Q298E | Missense Mutation (SNP) | VAF 86/269 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.324); catalogued as COSV59204150; called by muse, mutect2, varscan2
- SOX14 | c.284C>G p.P95R | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1243542412; called by muse, mutect2, varscan2
- SPTBN2 | c.6631C>G p.R2211G | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.173); catalogued as rs1333503788, COSV59449429; called by muse, mutect2, varscan2
- SRSF4 | c.832C>A p.Q278K | Missense Mutation (SNP) | VAF 96/258 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.037); catalogued as COSV100861426; called by muse, mutect2, varscan2
- TLX3 | c.615G>T p.M205I | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV99032105; called by muse, mutect2, varscan2
- TP53 | c.370del p.C124Afs*46 | Frame Shift Del (DEL) | VAF 55/104 reads (53%) | catalogued as COSV52680549, COSV52752618; called by mutect2, pindel, varscan2
- TPR | c.5620G>A p.E1874K | Missense Mutation (SNP) | VAF 48/494 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV66601597; called by muse, mutect2
- TRPC7 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as COSV61452697; called by muse, mutect2, varscan2
- VSIG4 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761396221; called by muse, mutect2
- WFIKKN1 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.452); catalogued as rs372514202, COSV50193096; called by muse, mutect2, varscan2
- WWC2 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs752815142; called by muse, mutect2, varscan2
- YTHDC1 | c.799C>G p.R267G | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV60009290; called by muse, varscan2
- ZNF831 | c.1802G>C p.R601T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.236); catalogued as COSV64040503; called by muse, mutect2
- ACAP3 | c.664C>A p.L222M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- ADRB1 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 84/232 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AJM1 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- APOB | c.6443A>G p.K2148R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ARHGAP17 | c.1093C>G p.Q365E | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ASB16 | c.767G>A p.G256D | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.96); PolyPhen benign (0.025); called by muse, mutect2
- AXDND1 | c.307C>G p.H103D | Missense Mutation (SNP) | VAF 18/367 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2
- CACNA1C | c.373C>G p.P125A | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CADPS | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 98/302 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, varscan2
- CALML6 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); called by mutect2, varscan2
- CCR1 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 83/319 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CD160 | c.334T>C p.C112R | Missense Mutation (SNP) | VAF 90/244 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); called by muse, varscan2
- CD1B | c.79T>A p.S27T | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.024); called by muse, mutect2
- CHST3 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 78/275 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- COL9A1 | c.2322dup p.A775Cfs*2 | Frame Shift Ins (INS) | VAF 84/319 reads (26%) | called by mutect2, pindel, varscan2
- DGKK | c.995C>G p.S332C | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- DNAH12 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH8 | c.11431C>G p.L3811V | Missense Mutation (SNP) | VAF 154/4653 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2
- DST | c.20875G>C p.E6959Q (on ENST00000361203 / NM_001374722.1; = p.E4656Q on NM_015548.5) | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- DUSP12 | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- EFCAB6 | c.1934A>T p.D645V | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- EGFR | c.829A>G p.M277V | Missense Mutation (SNP) | VAF 129/237 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EGFR | c.830T>A p.M277K | Missense Mutation (SNP) | VAF 133/241 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- ENTHD1 | c.1183C>G p.Q395E | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ESPNL | c.1414G>C p.D472H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- FAM131B | c.525_526+7del p.X175_splice | Splice Site (DEL) | VAF 22/86 reads (26%) | called by mutect2, pindel, varscan2
- FCRL5 | c.108A>C p.Q36H | Missense Mutation (SNP) | VAF 64/294 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); called by muse, varscan2
- FOXD2 | c.841C>G p.P281A | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FSIP2 | c.17044G>C p.E5682Q | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- GABRA3 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GCAT | c.965C>G p.S322C | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- GRAP2 | c.397A>G p.R133G | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- GRIK3 | c.2726C>T p.A909V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GUCY2F | c.490A>T p.T164S | Missense Mutation (SNP) | VAF 92/231 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- GYPA | c.436+2T>C p.X146_splice | Splice Site (SNP) | VAF 126/459 reads (27%) | called by muse, mutect2, varscan2
- GYS1 | c.1425G>A p.V475= | Splice Region (SNP) | VAF 40/126 reads (32%) | called by muse, mutect2, varscan2
- HAUS2 | c.435A>T p.R145S | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2
- IQCD | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- IRF1 | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.106); called by muse, mutect2
- KCND1 | c.1866G>T p.R622S | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL11 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- L3MBTL4 | c.1707G>C p.Q569H | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LDLRAD4 | c.759dup p.T254Hfs*47 | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by pindel, varscan2
- LVRN | c.1807C>G p.L603V | Missense Mutation (SNP) | VAF 109/566 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- LZTS1 | c.578T>C p.L193P | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MAP1B | c.1247G>C p.G416A | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP2 | c.1066A>T p.T356S | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.015); called by muse, mutect2
- MMP9 | c.1109G>C p.R370P | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MOV10 | c.825G>C p.E275D | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MRC2 | c.4326C>G p.I1442M | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- MSH3 | c.2665G>C p.E889Q | Missense Mutation (SNP) | VAF 84/356 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- MXRA5 | c.5153C>G p.P1718R | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- MYO18A | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NPTN | c.857C>G p.S286C | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- NPTN | c.436C>G p.Q146E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ORC3 | c.29G>T p.C10F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PBXIP1 | c.889C>G p.Q297E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- PDS5A | c.1132C>T p.H378Y | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PKDREJ | c.2812G>C p.D938H | Missense Mutation (SNP) | VAF 56/265 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PLCL1 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 92/320 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PLXNB3 | c.4663G>A p.V1555M | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- PMF1 | c.267G>A p.R89= | Splice Region (SNP) | VAF 9/54 reads (17%) | called by muse, varscan2
- PMS1 | c.2632G>C p.E878Q | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- PNOC | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PPIL4 | c.454C>G p.Q152E | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PRDM2 | c.4142A>G p.N1381S | Missense Mutation (SNP) | VAF 63/261 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRKD3 | c.944C>G p.S315* | Nonsense Mutation (SNP) | VAF 67/260 reads (26%) | called by muse, mutect2, varscan2
- PSMA8 | c.470C>G p.P157R | Missense Mutation (SNP) | VAF 76/170 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB33A | c.114A>C p.K38N | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SBK2 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SCAF8 | c.686T>G p.L229R | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SCAF8 | c.688G>C p.V230L | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); called by muse, mutect2
- SHANK1 | c.976C>G p.H326D | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SLC25A25 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SYCP3 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 116/385 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- SYTL5 | c.831+2T>C p.X277_splice | Splice Site (SNP) | VAF 38/97 reads (39%) | called by muse, mutect2, varscan2
- TEX10 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 56/221 reads (25%) | called by muse, mutect2, varscan2
- TMEM129 | c.197T>A p.L66Q | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TNRC6A | c.2162C>T p.S721F | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- TRPC3 | c.991G>A p.D331N (on ENST00000379645 / NM_001366479.2; = p.D258N on NM_003305.2) | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); called by muse, varscan2
- USP40 | c.908G>C p.G303A | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS41 | c.1438A>G p.I480V | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- WHAMM | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZC3H12A | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZNF672 | c.1236G>C p.Q412H | Missense Mutation (SNP) | VAF 13/243 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.79); called by muse, mutect2
- ZNFX1 | c.1145G>A p.R382K | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- ATP6V1B2 | c.15G>A p.A5= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs752788357; called by muse, mutect2, varscan2
- BTNL3 | c.198C>G p.L66= | Silent (SNP) | VAF 42/159 reads (26%) | called by muse, mutect2, varscan2
- C11orf95 | c.114C>T p.S38= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, varscan2
- CDCA3 | c.12C>G p.A4= | Silent (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- CDH18 | c.312C>T p.D104= | Silent (SNP) | VAF 314/615 reads (51%) | catalogued as rs368155280, COSV56951957; called by muse, mutect2, varscan2
- CDIP1 | c.294G>A p.G98= | Silent (SNP) | VAF 38/119 reads (32%) | called by muse, mutect2, varscan2
- CHRM2 | c.603C>T p.I201= | Silent (SNP) | VAF 185/818 reads (23%) | catalogued as COSV57777075; called by muse, mutect2, varscan2
- CILK1 | c.516G>A p.L172= | Silent (SNP) | VAF 34/125 reads (27%) | called by muse, mutect2, varscan2
- CLPSL2 | c.243G>T p.R81= | Silent (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2
- ESYT1 | c.1107C>T p.F369= | Silent (SNP) | VAF 62/192 reads (32%) | catalogued as COSV99919980; called by muse, mutect2, varscan2
- GARRE1 | c.1539T>C p.D513= | Silent (SNP) | VAF 49/133 reads (37%) | called by muse, mutect2, varscan2
- GCC1 | c.207C>G p.L69= | Silent (SNP) | VAF 42/193 reads (22%) | catalogued as rs1395265515, COSV50002338; called by muse, mutect2, varscan2
- H3C2 | c.186G>A p.L62= | Silent (SNP) | VAF 56/228 reads (25%) | catalogued as rs149213082, COSV52518058; called by muse, mutect2, varscan2
- HBG2 | c.357C>T p.F119= | Silent (SNP) | VAF 100/366 reads (27%) | catalogued as rs750889658, COSV57964338; called by muse, mutect2, varscan2
- IDO1 | c.489C>T p.F163= | Silent (SNP) | VAF 65/257 reads (25%) | called by muse, mutect2, varscan2
- IER3 | c.387C>T p.L129= | Silent (SNP) | VAF 44/116 reads (38%) | called by muse, mutect2, varscan2
- ITGBL1 | c.84C>T p.F28= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as rs947697260; called by muse, mutect2, varscan2
- KIF5C | c.534G>A p.E178= | Silent (SNP) | VAF 24/255 reads (9%) | called by muse, mutect2
- KLHL22 | c.600C>T p.L200= | Silent (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- LY6H | c.27C>T p.L9= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as rs1045539044; called by muse, mutect2, varscan2
- NAGS | c.1380G>A p.L460= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as rs1428233890; called by muse, mutect2, varscan2
- NEO1 | c.513G>A p.L171= | Silent (SNP) | VAF 83/275 reads (30%) | called by muse, mutect2, varscan2
- OPTC | c.666C>T p.G222= | Silent (SNP) | VAF 157/485 reads (32%) | called by muse, mutect2, varscan2
- PDRG1 | c.333G>A p.L111= | Silent (SNP) | VAF 26/99 reads (26%) | called by muse, mutect2, varscan2
- PPFIA2 | c.1044C>A p.L348= | Silent (SNP) | VAF 91/312 reads (29%) | called by muse, mutect2, varscan2
- PRNP | c.727C>T p.L243= | Silent (SNP) | VAF 46/208 reads (22%) | called by muse, mutect2, varscan2
- PRSS48 | c.15C>G p.G5= | Silent (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- SCN4A | c.2520C>G p.L840= | Silent (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- SLC35F3 | c.267G>A p.L89= (on ENST00000366617 / NM_001300845.1; = p.L158= on NM_173508.4) | Silent (SNP) | VAF 46/524 reads (9%) | called by muse, mutect2
- STXBP5 | c.489A>T p.R163= | Silent (SNP) | VAF 148/573 reads (26%) | called by muse, mutect2, varscan2
- SYNE2 | c.3000G>A p.R1000= | Silent (SNP) | VAF 581/923 reads (63%) | called by muse, mutect2, varscan2
- TCF21 | c.504G>A p.V168= | Silent (SNP) | VAF 38/109 reads (35%) | called by muse, mutect2, varscan2
- TRAC | c.396G>A p.L132= | Silent (SNP) | VAF 62/178 reads (35%) | called by muse, mutect2, varscan2
- TUBB4A | c.216C>T p.T72= | Silent (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- TUBGCP4 | c.241T>C p.L81= | Silent (SNP) | VAF 110/371 reads (30%) | called by muse, mutect2, varscan2
- WASHC5 | c.3379C>T p.L1127= | Silent (SNP) | VAF 140/502 reads (28%) | called by muse, mutect2, varscan2
- XIRP2 | c.468C>T p.T156= (on ENST00000628543; = p.T331= on NM_152381.6) | Silent (SNP) | VAF 78/359 reads (22%) | catalogued as rs376255866; called by muse, varscan2
- AC009053.1 | n.522C>A | RNA (SNP) | VAF 35/264 reads (13%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499266 G>A | 5'Flank (SNP) | VAF 38/161 reads (24%) | called by muse, mutect2, varscan2
- ARIH2 | c.-253C>T | 5'UTR (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- BAIAP2 | c.490-1784G>A | Intron (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- CFH | c.2956+13G>C | Intron (SNP) | VAF 206/612 reads (34%) | called by muse, mutect2, varscan2
- CSNK1G3 | c.179-23C>T | Intron (SNP) | VAF 18/72 reads (25%) | called by mutect2, varscan2
- DPP6 | c.*304G>A | 3'UTR (SNP) | VAF 19/81 reads (23%) | catalogued as rs764131463, COSV59600584; called by muse, mutect2, varscan2
- ERCC3 | c.28+60C>G | Intron (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- FGF22 | c.214+1092G>C | Intron (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- MDGA2 | c.281-41452G>A | Intron (SNP) | VAF 71/471 reads (15%) | called by muse, mutect2, varscan2
- NDUFA2 | c.*170G>A | 3'UTR (SNP) | VAF 47/217 reads (22%) | called by muse, mutect2, varscan2
- NIBAN1 | c.*48A>T | 3'UTR (SNP) | VAF 78/230 reads (34%) | catalogued as COSV100836628; called by muse, mutect2
- OR3A4P | n.439C>T | RNA (SNP) | VAF 57/235 reads (24%) | catalogued as rs765567710; called by muse, mutect2, varscan2
- PLB1 | c.937-336C>A | Intron (SNP) | VAF 27/82 reads (33%) | called by muse, mutect2, varscan2
- RRP12 | c.-138+6560G>C | Intron (SNP) | VAF 28/107 reads (26%) | called by muse, mutect2, varscan2
- TCP11X2 | chrX:102460500 G>T | 3'Flank (SNP) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- TGFBR3 | c.-221G>A | 5'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- TRIM6 | c.875-115C>T | Intron (SNP) | VAF 22/72 reads (31%) | catalogued as rs780824319; called by muse, mutect2, varscan2
- ZDHHC1 | c.-2C>G | 5'UTR (SNP) | VAF 27/209 reads (13%) | catalogued as rs1291278297; called by muse, mutect2, varscan2
